Somatic mutation profile of tumor specimen TCGA-DX-A6BK-01A (aliquot TCGA-DX-A6BK-01A-11D-A307-09) from TCGA case TCGA-DX-A6BK, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 85.3 years (31,159 days).
Specimen TCGA-DX-A6BK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5a28ca7-e3d1-448f-b5c2-05bb53865208.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6BK-10A (Blood Derived Normal), aliquot TCGA-DX-A6BK-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2ef43e9-ff81-4682-9b6b-0ea097ae4edf

The open-access MAF lists 51 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 30, Silent 12, Nonsense Mutation 7, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN4 | c.1552-1G>C p.X518_splice | Splice Site (SNP) | VAF 48/182 reads (26%) | catalogued as COSV99400179; called by muse, mutect2, varscan2
- ACTN4 | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53148353, COSV99400181; called by muse, mutect2, varscan2
- APEH | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 31/365 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.786); catalogued as rs1286126689, COSV99610767; called by muse, mutect2
- ARHGAP27 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as rs546150279, COSV99298989; called by muse, mutect2, varscan2
- BCORL1 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs147775035, COSV54390670, COSV99498258; called by muse, mutect2, varscan2
- CNN1 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.161); catalogued as COSV99372340; called by muse, mutect2
- CPNE1 | c.394C>T p.Q132* (on ENST00000352393; = p.Q137* on NM_003915.5) | Nonsense Mutation (SNP) | VAF 26/154 reads (17%) | catalogued as COSV58294234; called by muse, mutect2, varscan2
- DDX31 | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 8/115 reads (7%) | catalogued as COSV100936756; called by muse, mutect2
- EGFLAM | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748655132, COSV59318946; called by muse, mutect2, varscan2
- FABP7 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 19/250 reads (8%) | catalogued as COSV62956480; called by muse, mutect2
- FAM47C | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 56/336 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs182976429; called by muse, mutect2, varscan2
- FOXP3 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 17/145 reads (12%) | catalogued as COSV100873150; called by muse, mutect2, varscan2
- GEMIN4 | c.425A>C p.E142A | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as COSV100021355; called by muse, mutect2, varscan2
- GTF2I | c.1279G>T p.E427* (on ENST00000573035 / NM_032999.4; = p.E386* on NM_001518.5) | Nonsense Mutation (SNP) | VAF 68/1013 reads (7%) | catalogued as COSV100259531; called by muse, mutect2
- HAUS1 | c.690G>C p.Q230H | Missense Mutation (SNP) | VAF 1162/1377 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs374962238, COSV99959465; called by muse, varscan2
- HAUS6 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs750326234, COSV100787216; called by muse, mutect2, varscan2
- HERC2 | c.13726G>A p.D4576N | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99873604; called by mutect2, varscan2
- LAMC3 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs146887458, COSV63090467; called by muse, mutect2, varscan2
- MCF2L2 | c.2332A>T p.M778L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100192505; called by muse, mutect2, varscan2
- NOP14 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs149998901; called by muse, mutect2, varscan2
- OR10H1 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 109/444 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as rs371707981; called by muse, varscan2
- PCLO | c.4318G>T p.E1440* | Nonsense Mutation (SNP) | VAF 18/214 reads (8%) | catalogued as COSV100432364, COSV61662532; called by muse, mutect2
- PKHD1L1 | c.8628G>T p.Q2876H | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.212); catalogued as COSV101006105; called by muse, mutect2, varscan2
- PLCG1 | c.1450A>T p.N484Y | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV99718832; called by muse, mutect2, varscan2
- PRKACA | c.806T>A p.L269Q | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99513813; called by muse, mutect2, varscan2
- PRPF8 | c.2950A>T p.M984L | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100517484; called by muse, mutect2
- RAB11FIP5 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as COSV99242022; called by muse, mutect2, varscan2
- RNF38 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.857); catalogued as rs1372589143, COSV99425045; called by muse, varscan2
- SIM1 | c.2089A>C p.N697H | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.359); catalogued as COSV99492338; called by muse, mutect2, varscan2
- SLC35A2 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as rs1023107993, COSV99504257; called by mutect2, varscan2
- SPHKAP | c.2480C>A p.T827K | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100764114; called by muse, mutect2, varscan2
- SPTB | c.1128C>A p.N376K | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101072125; called by muse, mutect2
- TREML4 | c.401C>G p.T134S | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV100422909; called by muse, mutect2, varscan2
- WWP1 | c.2519A>G p.N840S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1276075425, COSV99616379; called by muse, varscan2
- XKR7 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs779419531, COSV73813506; called by muse, mutect2, varscan2
- ZBED9 | c.1339G>C p.V447L | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV101509236; called by muse, mutect2
- ZC3H13 | c.2433G>C p.R811S | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV99668109, COSV99668889; called by muse, mutect2
- AUTS2 | c.3727G>T p.E1243* | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- MEN1 | c.1244del p.F415Sfs*35 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- C16orf78 | c.297C>T p.D99= | Silent (SNP) | VAF 25/166 reads (15%) | catalogued as rs143423404; called by muse, mutect2, varscan2
- DCC | c.828C>T p.G276= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as COSV100499966, COSV59108704; called by muse, mutect2, varscan2
- KRT32 | c.447C>A p.T149= | Silent (SNP) | VAF 32/159 reads (20%) | catalogued as rs745874255, COSV99863022; called by muse, mutect2, varscan2
- MAP3K15 | c.2550G>A p.P850= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as rs1478185273, COSV100134691; called by muse, mutect2, varscan2
- RNF38 | c.96C>T p.F32= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV99425046; called by muse, varscan2
- RP1 | c.3894C>T p.F1298= | Silent (SNP) | VAF 26/343 reads (8%) | catalogued as COSV55115168; called by muse, mutect2
- SYCN | c.141C>T p.P47= | Silent (SNP) | VAF 82/463 reads (18%) | catalogued as rs746165928, COSV100355791, COSV59213360; called by muse, mutect2, varscan2
- TAS2R40 | c.105G>T p.G35= | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as COSV101282995; called by muse, mutect2
- TEAD3 | c.295C>A p.R99= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV100132400; called by muse, mutect2, varscan2
- TRIP6 | c.1314G>A p.L438= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV99566669; called by muse, mutect2, varscan2
- VWF | c.2352A>G p.E784= | Silent (SNP) | VAF 12/149 reads (8%) | catalogued as COSV99778999; called by muse, mutect2
- ZNF467 | c.1773C>G p.P591= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100117931; called by muse, mutect2, varscan2
